Gene-level copy-number profile of tumor specimen TCGA-FS-A1Z7-06A from TCGA case TCGA-FS-A1Z7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 20.0 years (7,307 days).
Specimen TCGA-FS-A1Z7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.5065e17b-f52b-45ca-90e2-766cb0372f2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1Z7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92f85cc9-4203-482d-b286-58e0fa40acef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 9,953; copy number 2: 40,281; copy number 3: 6,552; copy number 4: 2,956; copy number 6: 40; copy number 8: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1Z7-06A-11D-A191-01): tumor purity 0.61, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:87,659,613–87,971,930, 7 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,318,861, 12 genes, copy number 8: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:95,471,835–97,181,763, 25 genes, copy number 6 (within-gene range 4–6): AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21.
- chr7:120,005,976–121,341,104, 15 genes, copy number 6: RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16.

Autosomal genes at a single copy (total copy number 1): 7,532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
